Gene-level copy-number profile of tumor specimen TCGA-73-4676-01A from TCGA case TCGA-73-4676, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIA; Age at diagnosis: 45.8 years (16,746 days).
Specimen TCGA-73-4676-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUAD.4f57e049-a775-4fd6-8293-358061dd56c3.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-73-4676-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/f005fecf-9d3a-47dc-8819-83f9927e0fd3

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 94; copy number 2: 39,368; copy number 3: 7,104; copy number 4: 11,605; copy number 5: 624; copy number 6: 16; copy number 7: 1,009.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-73-4676-01A-01D-1752-01): tumor purity 0.77, ploidy 1.31, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,649 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,343,180–169,630,193, 1,008 genes, copy number 7 (broad region; genes not listed).
- chr1:169,690,665–169,711,702, 1 gene, copy number 7: SELL.
- chr8:11,676,959–11,999,468, 16 genes, copy number 6: GATA4, C8orf49, NEIL2, SUB1P1, FDFT1, AC069185.1, CTSB, AC025857.1, OR7E158P, OR7E161P, AC107918.5, AC107918.6, DEFB136, DEFB135, DEFB134, AC107918.3.
- chr17:63,938,554–83,095,122, 624 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 94. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
